Somatic mutation profile of tumor specimen TCGA-04-1353-01A (aliquot TCGA-04-1353-01A-01D-1526-09) from TCGA case TCGA-04-1353, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Age at diagnosis: 64.6 years (23,611 days).
Specimen TCGA-04-1353-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42ee979a-da0d-406b-ab48-24fecaf772e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1353-11B (Solid Tissue Normal), aliquot TCGA-04-1353-11B-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb81a631-7f5d-4609-b1ce-5527de41de53

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC008397.2 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99442098; called by muse, mutect2
- BPI | c.208G>A p.D70N (on ENST00000262865; = p.D66N on NM_001725.3) | Missense Mutation (SNP) | VAF 144/379 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs757310335, COSV99480877; called by muse, mutect2, varscan2
- CALR | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.235); catalogued as rs763131258, COSV57137895; called by muse, varscan2
- CENPB | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.682); catalogued as COSV100713587; called by muse, mutect2, varscan2
- NLRP2 | c.2715G>C p.W905C | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as COSV99672548; called by muse, mutect2
- RTEL1 | c.2949C>G p.S983R | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs759760316, COSV100542705, COSV58894439; called by muse, varscan2
- DPYSL5 | c.33C>G p.L11= | Silent (SNP) | VAF 61/303 reads (20%) | catalogued as COSV99982659; called by muse, mutect2, varscan2
- FAT2 | c.3855C>T p.D1285= | Silent (SNP) | VAF 95/498 reads (19%) | catalogued as COSV99943831; called by muse, mutect2, varscan2
- HS3ST6 | c.936G>A p.V312= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV99562830; called by muse, mutect2, varscan2
- NR5A1 | c.507G>A p.L169= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV65295058; called by muse, mutect2, varscan2
- PLPPR4 | c.1911G>T p.P637= | Silent (SNP) | VAF 96/228 reads (42%) | catalogued as rs201385642, COSV100926892, COSV64567674; called by muse, mutect2, varscan2
- PLXNA1 | c.4935C>T p.P1645= | Silent (SNP) | VAF 90/206 reads (44%) | catalogued as rs527394103, COSV99303885; called by muse, mutect2, varscan2
- ARHGAP39 | c.2522-3592G>C | Intron (SNP) | VAF 178/683 reads (26%) | catalogued as COSV99432019; called by muse, varscan2
